Somatic mutation profile of tumor specimen 0DFWBY from CCDI case PBBSAX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 16.5 years (6,031 days).
Specimen 0DFWBY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31053c28-bca2-48aa-a6bc-b00143121e93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFWBZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26f655f5-b5c0-4e31-b3d6-59cbd3eb6e36

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 123/1188 reads (10%) | catalogued as rs779866340, COSV53982838, COSV99684621; ClinVar: uncertain significance; called by muse, varscan2
- ARHGAP20 | c.630C>T p.Y210= | Splice Region (SNP) | VAF 252/699 reads (36%) | catalogued as rs771316747, COSV52818215; called by muse, varscan2
- MFSD1 | c.1126A>G p.M376V | Missense Mutation (SNP) | VAF 140/964 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs1457038934; called by muse, varscan2
- DNER | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.02); called by muse, varscan2
